Somatic mutation profile of tumor specimen TCGA-55-7995-01A (aliquot TCGA-55-7995-01A-11D-2184-08) from TCGA case TCGA-55-7995, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 73.5 years (26,837 days).
Specimen TCGA-55-7995-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b394698-3077-43ba-b32f-678399805f34.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-7995-10A (Blood Derived Normal), aliquot TCGA-55-7995-10A-01D-2184-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d61d17d6-916d-4f9e-b2bc-d878ccfad1c6

The open-access MAF lists 719 somatic variants for this specimen: 552 protein-altering or splice-affecting, 152 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 498, Silent 152, Nonsense Mutation 19, Splice Site 12, Frame Shift Del 12, RNA 5, Intron 5, Splice Region 5, 5'Flank 3, Frame Shift Ins 2, Nonstop Mutation 2, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1321C>T p.R441W (on ENST00000281708 / NM_001349798.2; = p.R361W on NM_018315.5) | Missense Mutation (SNP) | VAF 51/263 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55897212, COSV55936558; called by muse, mutect2, varscan2
- TP53 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 36/78 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.2665C>T p.P889S | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV100229271; called by muse, mutect2, varscan2
- ABCB10 | c.1468G>T p.G490C | Missense Mutation (SNP) | VAF 68/181 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100748046, COSV100748073; called by muse, mutect2, varscan2
- ABCC1 | c.2162C>G p.S721C | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100580098; called by muse, mutect2, varscan2
- ABCC4 | c.2625C>G p.F875L | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as COSV100972683; called by muse, mutect2, varscan2
- ABCC4 | c.1161+1G>A p.X387_splice | Splice Site (SNP) | VAF 33/109 reads (30%) | catalogued as COSV100972685; called by muse, mutect2, varscan2
- ABCC8 | c.2608G>T p.A870S | Missense Mutation (SNP) | VAF 21/224 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV100217593; called by muse, mutect2, varscan2
- ACOX1 | c.1504C>T p.L502F | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV99503860; called by muse, mutect2, varscan2
- ACSL6 | c.375G>T p.E125D (on ENST00000379240; = p.E150D on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as COSV99734402; called by muse, mutect2, varscan2
- ADAMTS18 | c.2903A>C p.E968A | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as COSV99273747; called by muse, mutect2, varscan2
- ADAMTS2 | c.3128A>G p.Q1043R | Missense Mutation (SNP) | VAF 154/302 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV99283449; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4984A>T p.T1662S | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.207); catalogued as COSV99720452; called by muse, mutect2, varscan2
- ADGRG2 | c.2801G>T p.S934I (on ENST00000379869 / NM_001079858.3; = p.S931I on NM_005756.4) | Missense Mutation (SNP) | VAF 45/234 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as COSV100492526; called by muse, mutect2, varscan2
- ADGRL3 | c.3805C>A p.L1269I (on ENST00000506720 / NM_001322402.2; = p.L1201I on NM_015236.6) | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV101547329; called by muse, mutect2
- ADGRL4 | c.1934C>A p.T645K | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100876393; called by muse, mutect2, varscan2
- ADNP | c.1709A>G p.N570S | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.109); catalogued as COSV62425231; called by muse, mutect2, varscan2
- ALK | c.1439G>A p.C480Y | Missense Mutation (SNP) | VAF 112/184 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758547033, COSV101202168, COSV101202492; called by muse, mutect2, varscan2
- ALMS1 | c.8590G>C p.G2864R | Missense Mutation (SNP) | VAF 59/96 reads (61%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as COSV100043313; called by muse, mutect2, varscan2
- ALOXE3 | c.2073G>T p.Q691H | Missense Mutation (SNP) | VAF 62/115 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV100559876; called by muse, mutect2, varscan2
- ALPK1 | c.2184G>T p.R728S | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV99454901; called by muse, mutect2
- ALPP | c.465G>A p.M155I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV67395595; called by muse, varscan2
- ALPP | c.466A>T p.N156Y | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as COSV101235175; called by muse, varscan2
- ANK2 | c.1213G>T p.A405S | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100003343; called by muse, mutect2, varscan2
- ANK2 | c.7571A>T p.Q2524L | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100003346; called by muse, mutect2, varscan2
- ANKRD24 | c.787C>G p.L263V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.242); catalogued as COSV53675478, COSV99517978; called by muse, mutect2, varscan2
- ANKRD37 | c.288C>A p.N96K | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.803); catalogued as COSV99249241; called by muse, mutect2, varscan2
- ANKS1B | c.638T>A p.L213Q | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100247190; called by muse, mutect2, varscan2
- ANKS4B | c.610A>G p.T204A | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.249); catalogued as COSV100289906; called by muse, mutect2, varscan2
- ANO3 | c.2159G>C p.W720S | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56812169, COSV99884714; called by muse, mutect2, varscan2
- ANO4 | c.1274G>A p.G425E (on ENST00000392977 / NM_001286615.2; = p.G390E on NM_178826.4) | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.17); catalogued as COSV100153491; called by muse, mutect2, varscan2
- ANXA5 | c.32A>T p.D11V | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as COSV99634617; called by muse, mutect2, varscan2
- ANXA6 | c.877T>A p.F293I | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100637059; called by muse, mutect2, varscan2
- APOB | c.10834G>A p.D3612N | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as COSV99267163; called by muse, mutect2, varscan2
- APOOL | c.719G>T p.G240V | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV100261026; called by muse, mutect2
- APPBP2 | c.424G>C p.V142L | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as COSV99319815; called by muse, mutect2, varscan2
- ARHGAP29 | c.2500G>T p.E834* | Nonsense Mutation (SNP) | VAF 26/89 reads (29%) | catalogued as COSV99558713; called by muse, mutect2, varscan2
- ARHGAP31 | c.258G>T p.Q86H | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV99957525; called by muse, mutect2, varscan2
- ARHGAP4 | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.179); catalogued as rs374827115, COSV100604177; called by muse, varscan2
- ARHGEF19 | c.1963G>T p.D655Y | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99580668; called by muse, mutect2, varscan2
- ARHGEF40 | c.2117A>G p.E706G | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as COSV100070584; called by muse, mutect2, varscan2
- ARSF | c.608T>A p.L203Q | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as COSV100839576; called by muse, mutect2, varscan2
- ASCC2 | c.2101G>T p.G701W | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100316430; called by muse, mutect2, varscan2
- ASCC2 | c.1274G>A p.G425E | Missense Mutation (SNP) | VAF 182/431 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.047); catalogued as COSV100316431; called by muse, mutect2, varscan2
- ASPHD1 | c.253G>T p.G85W | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58102642; called by muse, mutect2, varscan2
- ASTN2 | c.3609C>G p.D1203E (on ENST00000313400 / NM_001365069.1; = p.D1152E on NM_014010.5) | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV99941280; called by muse, mutect2, varscan2
- ATG3 | c.697T>G p.Y233D | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99344304; called by muse, mutect2, varscan2
- ATP13A3 | c.1949A>G p.Y650C | Missense Mutation (SNP) | VAF 27/194 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99757481; called by muse, mutect2, varscan2
- ATP1A2 | c.2047A>T p.T683S | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.018); catalogued as COSV100768077; called by muse, mutect2, varscan2
- ATP1A4 | c.2671G>T p.G891C | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63628926; called by muse, mutect2, varscan2
- BCAS4 | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.701); catalogued as COSV99372717; called by muse, mutect2, varscan2
- BEND3 | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.32); catalogued as rs781792938, COSV100944597; called by muse, mutect2, varscan2
- BEST2 | c.506A>G p.K169R | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.147); catalogued as COSV99244607; called by muse, mutect2, varscan2
- BIRC6 | c.4510G>T p.D1504Y | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101428585, COSV70205060; called by muse, mutect2, varscan2
- BIRC6 | c.5684A>T p.H1895L | Missense Mutation (SNP) | VAF 35/56 reads (63%) | SIFT tolerated (0.26); PolyPhen benign (0.236); catalogued as COSV101428586; called by muse, mutect2, varscan2
- BMP15 | c.512C>G p.S171C | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.846); catalogued as COSV99399472; called by muse, mutect2, varscan2
- BRPF3 | c.2161C>T p.R721C | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); catalogued as rs1288578443, COSV100326081; called by muse, mutect2, varscan2
- BRWD3 | c.4097T>A p.I1366K | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV100956368; called by muse, mutect2, varscan2
- C1orf87 | c.1131G>T p.W377C | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100967210; called by muse, mutect2, varscan2
- CALN1 | c.255C>G p.D85E (on ENST00000329008 / NM_001017440.3; = p.D127E on NM_031468.4) | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.348); catalogued as COSV100208559; called by muse, mutect2, varscan2
- CAMTA1 | c.2598G>C p.Q866H | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.359); catalogued as COSV100351855; called by muse, mutect2, varscan2
- CASKIN2 | c.1193-2A>T p.X398_splice | Splice Site (SNP) | VAF 7/31 reads (23%) | catalogued as COSV100050761; called by muse, mutect2, varscan2
- CATSPER2 | c.64C>G p.L22V | Missense Mutation (SNP) | VAF 129/252 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100390936; called by muse, mutect2, varscan2
- CBLL2 | c.770C>A p.P257H | Missense Mutation (SNP) | VAF 69/352 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.239); catalogued as COSV100081694; called by muse, mutect2, varscan2
- CBX4 | c.798G>A p.M266I | Missense Mutation (SNP) | VAF 59/366 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV99490488; called by muse, mutect2, varscan2
- CCER1 | c.1053G>T p.E351D | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV100727123; called by muse, mutect2, varscan2
- CCN1 | c.789A>T p.E263D | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV101486139; called by muse, mutect2, varscan2
- CCNB3 | c.2151C>G p.S717R | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.326); catalogued as COSV99329553; called by muse, mutect2, varscan2
- CCNT2 | c.889A>G p.T297A | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV99751035; called by muse, mutect2
- CD40LG | c.288G>A p.K96= | Splice Region (SNP) | VAF 41/65 reads (63%) | catalogued as COSV101033533; called by muse, mutect2, varscan2
- CENPC | c.1443G>C p.V481= | Splice Region (SNP) | VAF 3/16 reads (19%) | catalogued as COSV99894293; called by muse, mutect2
- CENPE | c.8093G>T p.C2698F | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99478756; called by muse, mutect2, varscan2
- CENPE | c.3409C>T p.Q1137* | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | catalogued as COSV54383160, COSV99476769; called by muse, mutect2, varscan2
- CENPL | c.482G>T p.W161L | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV100616421; called by muse, mutect2, varscan2
- CEP128 | c.2624del p.Q875Rfs*7 | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | catalogued as COSV99823856, COSV99824481; called by mutect2, pindel, varscan2
- CEP135 | c.2523G>T p.L841F | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99954370; called by muse, mutect2, varscan2
- CEP85L | c.286A>G p.T96A | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV100821340; called by muse, mutect2, varscan2
- CFAP44 | c.7G>T p.E3* | Nonsense Mutation (SNP) | VAF 68/166 reads (41%) | catalogued as COSV99870194; called by muse, mutect2, varscan2
- CFAP52 | c.1125G>T p.M375I | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs904633446, COSV100235478; called by muse, mutect2, varscan2
- CFAP54 | c.4886G>T p.R1629L | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100733270, COSV61570724; called by muse, mutect2, varscan2
- CFHR3 | c.992A>T p.*331Lext*44 | Nonstop Mutation (SNP) | VAF 69/198 reads (35%) | catalogued as COSV100807700; called by muse, mutect2, varscan2
- CFTR | c.1588A>T p.I530F | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.113); catalogued as CM090070, COSV99138351; called by muse, mutect2, varscan2
- CHM | c.1917C>A p.F639L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100753556; called by muse, mutect2, varscan2
- CHRD | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99200649; called by muse, mutect2, varscan2
- CHRDL1 | c.287C>A p.S96Y (on ENST00000372045; = p.S102Y on NM_145234.4) | Missense Mutation (SNP) | VAF 98/250 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV99488529; called by muse, mutect2, varscan2
- CHSY3 | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100519705; called by muse, mutect2, varscan2
- CILP2 | c.1051C>A p.P351T | Missense Mutation (SNP) | VAF 57/110 reads (52%) | SIFT tolerated (0.57); PolyPhen benign (0.158); catalogued as COSV99365047; called by muse, mutect2, varscan2
- CLASP1 | c.108G>T p.K36N | Missense Mutation (SNP) | VAF 59/105 reads (56%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.691); catalogued as COSV99756519; called by muse, mutect2, varscan2
- CLCA4 | c.1190G>C p.G397A | Missense Mutation (SNP) | VAF 34/229 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.062); catalogued as COSV55368865, COSV99760719; called by muse, mutect2, varscan2
- CLCN5 | c.169G>A p.G57S | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.59); catalogued as rs782720805, COSV100260332; called by muse, mutect2, varscan2
- CLEC6A | c.308G>T p.S103I | Missense Mutation (SNP) | VAF 75/278 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV101165688; called by muse, mutect2, varscan2
- CLIC5 | c.715G>A p.D239N (on ENST00000185206 / NM_001370649.1; = p.D80N on NM_016929.5) | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as COSV99485096; called by muse, mutect2, varscan2
- COL22A1 | c.4819C>T p.P1607S | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs761832409, COSV100279919; called by muse, mutect2, varscan2
- COL2A1 | c.862G>T p.G288C | Missense Mutation (SNP) | VAF 115/436 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100477186; called by muse, mutect2, varscan2
- COL4A2 | c.3205C>T p.R1069W | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs200165414, CD126382; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A6 | c.2623G>T p.V875L | Missense Mutation (SNP) | VAF 48/214 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0.27); catalogued as COSV100564798; called by muse, mutect2, varscan2
- COL6A3 | c.3709C>T p.L1237F | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99800404; called by muse, mutect2, varscan2
- COLEC12 | c.527G>T p.G176V | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV101232127; called by muse, mutect2, varscan2
- COPB1 | c.1567A>G p.T523A | Missense Mutation (SNP) | VAF 82/171 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV99999817; called by muse, mutect2, varscan2
- COQ3 | c.1042G>T p.G348* | Nonsense Mutation (SNP) | VAF 74/238 reads (31%) | catalogued as COSV99632912; called by muse, mutect2, varscan2
- CPNE6 | c.206C>A p.P69H | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99393637; called by muse, mutect2, varscan2
- CPT2 | c.1652G>A p.G551D | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99598280; called by muse, mutect2, varscan2
- CPXCR1 | c.449G>T p.S150I | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as COSV52161711, COSV99342362; called by muse, mutect2, varscan2
- CRB1 | c.1175T>A p.I392N | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.717); catalogued as COSV100958033; called by muse, mutect2, varscan2
- CRB1 | c.2131T>A p.Y711N | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV100958035; called by muse, mutect2, varscan2
- CRNKL1 | c.320C>A p.S107Y | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.014); catalogued as COSV55623529, COSV99846081; called by muse, mutect2, varscan2
- CRY1 | c.586G>T p.E196* | Nonsense Mutation (SNP) | VAF 43/199 reads (22%) | catalogued as rs146335177; called by muse, mutect2, varscan2
- CRYBG3 | c.7239G>C p.L2413F | Missense Mutation (SNP) | VAF 42/242 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as rs1420855823, COSV99477331; called by muse, mutect2, varscan2
- CRYZ | c.689T>G p.L230R | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100558669; called by muse, mutect2, varscan2
- CSHL1 | c.104T>A p.L35H | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99368117; called by muse, mutect2, varscan2
- CSMD2 | c.5426C>A p.S1809Y | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99593568; called by muse, mutect2, varscan2
- CUBN | c.51A>G p.I17M | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1376800123, COSV100910640; called by muse, mutect2, varscan2
- CXorf38 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV100010498, COSV59947711; called by muse, mutect2, varscan2
- CYTH1 | c.467G>T p.G156V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100739387; called by mutect2, varscan2
- CYTH4 | c.809-1G>T p.X270_splice | Splice Site (SNP) | VAF 41/143 reads (29%) | catalogued as rs11703243, COSV99958104; called by muse, mutect2, varscan2
- DACT1 | c.1294A>T p.R432W | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); catalogued as COSV100242032; called by muse, mutect2, varscan2
- DCDC1 | c.79G>T p.V27L | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV100663957; called by muse, mutect2, varscan2
- DCK | c.313A>T p.I105L | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.131); catalogued as COSV99709267; called by muse, mutect2, varscan2
- DCX | c.212C>A p.A71D | Missense Mutation (SNP) | VAF 92/208 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100576684, COSV57573171; called by muse, mutect2, varscan2
- DDRGK1 | c.804C>A p.F268L | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as COSV100621509; called by muse, mutect2
- DEPDC4 | c.211C>T p.L71F | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100147404; called by muse, mutect2, varscan2
- DHX40 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs759142376, COSV52069495, COSV99233178; called by muse, mutect2
- DIAPH3 | c.3307G>T p.V1103F (on ENST00000400324 / NM_001042517.2; = p.V840F on NM_030932.3) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.08); catalogued as COSV99934107; called by muse, mutect2, varscan2
- DIP2B | c.4168C>T p.L1390F | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56582007, COSV99999130; called by muse, mutect2, varscan2
- DLC1 | c.267C>A p.D89E | Missense Mutation (SNP) | VAF 53/209 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.018); catalogued as COSV99364738; called by muse, mutect2, varscan2
- DLGAP3 | c.1343G>T p.R448L | Missense Mutation (SNP) | VAF 49/179 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as COSV52391347, COSV99333045; called by muse, mutect2, varscan2
- DMBX1 | c.425A>G p.K142R | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as COSV100760857; called by muse, mutect2
- DMD | c.4231C>G p.Q1411E | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.327); catalogued as CM149353, COSV100821892; called by muse, mutect2, varscan2
- DNAH2 | c.2590C>G p.Q864E | Missense Mutation (SNP) | VAF 52/89 reads (58%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV101209524, COSV104430286; called by muse, mutect2, varscan2
- DNAI4 | c.757A>T p.T253S | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0.093); catalogued as COSV100925237; called by muse, mutect2, varscan2
- DNAJC10 | c.826C>G p.R276G | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV51148604, COSV99899513; called by muse, mutect2, varscan2
- DNAJC13 | c.5442G>T p.M1814I | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV53446032, COSV99607832; called by muse, mutect2, varscan2
- DNAJC28 | c.110A>G p.N37S | Missense Mutation (SNP) | VAF 82/151 reads (54%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1568996740, COSV100074750; called by muse, mutect2, varscan2
- DPP6 | c.21C>G p.I7M | Missense Mutation (SNP) | VAF 55/78 reads (71%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.924); catalogued as COSV101341805, COSV68053472; called by muse, mutect2, varscan2
- DQX1 | c.1432C>A p.L478M | Missense Mutation (SNP) | VAF 160/256 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV101099169; called by muse, mutect2, varscan2
- DSEL | c.1559A>T p.Q520L | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100025954; called by muse, varscan2
- DST | c.7498G>T p.V2500F | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as rs1249621213, COSV99758839; called by muse, mutect2, varscan2
- DYNC1H1 | c.6842C>A p.T2281K | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100795222; called by muse, mutect2, varscan2
- DZIP3 | c.3365G>A p.R1122K | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1226854918, COSV100847969; called by muse, mutect2, varscan2
- E2F2 | c.403G>T p.G135W | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100674851; called by muse, mutect2, varscan2
- EID2 | c.358G>T p.G120C | Missense Mutation (SNP) | VAF 82/183 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.678); catalogued as COSV101180504; called by muse, varscan2
- ELAPOR2 | c.2233G>T p.G745W (on ENST00000450689 / NM_001142749.3; = p.G578W on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV99789229; called by muse, mutect2, varscan2
- EMID1 | c.1204+1G>T p.X402_splice | Splice Site (SNP) | VAF 25/91 reads (27%) | catalogued as rs1165964344, COSV100469209; called by muse, mutect2, varscan2
- EMILIN2 | c.559C>A p.L187I | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99598773; called by muse, mutect2, varscan2
- EML5 | c.811G>T p.V271L | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV100716044; called by muse, mutect2
- EP400 | c.6853G>C p.A2285P | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.955); catalogued as COSV100201945, COSV57762194; called by muse, mutect2, varscan2
- ERICH3 | c.3253G>C p.A1085P | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); catalogued as COSV100445232; called by muse, mutect2, varscan2
- EYS | c.1163G>T p.C388F | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0.01); catalogued as COSV100676972; called by muse, mutect2
- FAM135B | c.2795A>C p.H932P | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99426294; called by muse, mutect2, varscan2
- FAM47A | c.1006C>A p.H336N | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.829); catalogued as COSV100650013; called by muse, mutect2, varscan2
- FAM47C | c.1960C>A p.L654I | Missense Mutation (SNP) | VAF 84/193 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.885); catalogued as COSV100792872; called by muse, varscan2
- FAM83C | c.1747A>T p.R583W | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.704); catalogued as COSV100981643; called by muse, mutect2, varscan2
- FASLG | c.760G>T p.A254S | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT tolerated (0.74); PolyPhen benign (0.421); catalogued as COSV100390581; called by muse, mutect2, varscan2
- FBXO34 | c.631G>T p.V211F | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100572107; called by muse, mutect2, varscan2
- FGB | c.1081G>C p.V361L | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV100122526, COSV57418076; called by muse, mutect2, varscan2
- FLG | c.4571C>A p.P1524H | Missense Mutation (SNP) | VAF 222/598 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.265); catalogued as COSV100911940; called by muse, mutect2, varscan2
- FLG | c.3010C>A p.Q1004K | Missense Mutation (SNP) | VAF 173/528 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1486805206, COSV100911942; called by muse, mutect2, varscan2
- FOLH1 | c.517G>T p.D173Y | Missense Mutation (SNP) | VAF 64/163 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as rs778134535, COSV57046475, COSV57049371; called by muse, varscan2
- FPR1 | c.997G>T p.D333Y | Missense Mutation (SNP) | VAF 66/144 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.491); catalogued as COSV100494187, COSV59053430; called by muse, mutect2, varscan2
- FRZB | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 10/56 reads (18%) | catalogued as COSV54555483, COSV99717500; called by muse, mutect2, varscan2
- FSCB | c.119G>T p.S40I | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV100469674; called by muse, mutect2, varscan2
- FUT10 | c.1145A>G p.N382S | Missense Mutation (SNP) | VAF 71/182 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.869); catalogued as rs1340066547, COSV100161650; called by muse, mutect2, varscan2
- FXYD6 | c.104A>G p.Q35R | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV99502606; called by muse, mutect2, varscan2
- G2E3 | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99249831; called by muse, mutect2, varscan2
- GABBR2 | c.750C>G p.I250M | Missense Mutation (SNP) | VAF 110/189 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99411058; called by muse, mutect2, varscan2
- GAPVD1 | c.2261G>T p.R754M | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as COSV99783616; called by muse, mutect2, varscan2
- GATA1 | c.9C>A p.F3L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as COSV64961928; called by muse, mutect2, varscan2
- GCM1 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs771101188, COSV99452569; called by muse, mutect2, varscan2
- GCM2 | c.1486G>T p.G496C | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV101069593, COSV65275342; called by muse, mutect2, varscan2
- GGTLC1 | c.355G>A p.G119S | Missense Mutation (SNP) | VAF 52/351 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.781); catalogued as rs746307097, COSV53848829; called by muse, mutect2, varscan2
- GHDC | c.1508C>T p.P503L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs756212657, COSV99511606; called by muse, varscan2
- GIMAP1 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.969); catalogued as COSV56187001; called by muse, mutect2, varscan2
- GNG7 | c.176T>G p.F59C | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101191370; called by muse, mutect2, varscan2
- GNL3L | c.913C>A p.P305T | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100328543; called by muse, mutect2, varscan2
- GNL3L | c.914C>A p.P305Q | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100328545; called by muse, mutect2, varscan2
- GPD1L | c.568A>G p.I190V | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99245851; called by muse, mutect2, varscan2
- GPM6A | c.621G>A p.L207= | Splice Region (SNP) | VAF 11/62 reads (18%) | catalogued as COSV54562124; called by muse, mutect2, varscan2
- GPR34 | c.85C>G p.H29D | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100587582; called by muse, varscan2
- GRID2 | c.579G>T p.M193I | Missense Mutation (SNP) | VAF 52/159 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.025); catalogued as rs267600299, COSV56207593, COSV99944812; called by muse, mutect2, varscan2
- GRID2 | c.1315C>G p.R439G | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV56185846, COSV56207492; called by muse, mutect2, varscan2
- GRIN2B | c.1231C>A p.L411M | Missense Mutation (SNP) | VAF 69/239 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101663135; called by muse, mutect2, varscan2
- GRIN3A | c.1024A>G p.T342A | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100701332; called by muse, mutect2, varscan2
- GRIP1 | c.35T>A p.I12N | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV99670462; called by muse, mutect2, varscan2
- GTF2E1 | c.954C>A p.N318K | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.544); catalogued as COSV99382113; called by muse, mutect2, varscan2
- GTF2IRD2B | c.2389C>T p.H797Y | Missense Mutation (SNP) | VAF 39/242 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV100441224; called by muse, mutect2, varscan2
- H4C3 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.243); catalogued as COSV100619624; called by muse, mutect2, varscan2
- HAND1 | c.22G>T p.A8S | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs371033200, COSV99164001; called by muse, mutect2, varscan2
- HEPH | c.2596G>T p.E866* (on ENST00000343002; = p.E599* on NM_014799.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 21/118 reads (18%) | catalogued as COSV100295429; called by muse, mutect2, varscan2
- HERC2 | c.13201C>T p.R4401W | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762578420, COSV55328037; called by muse, mutect2, varscan2
- HGSNAT | c.748G>C p.A250P | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV101108328; called by muse, mutect2, varscan2
- HIRA | c.2531C>T p.A844V | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as rs781964027, COSV99600767; called by muse, mutect2, varscan2
- HIVEP2 | c.1748G>T p.G583V | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV99174956; called by muse, mutect2, varscan2
- HOXB7 | c.71G>C p.G24A | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.518); catalogued as COSV53311738, COSV99494155; called by muse, mutect2, varscan2
- HPSE2 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV100986072; called by muse, mutect2, varscan2
- HRNR | c.3281C>A p.A1094D | Missense Mutation (SNP) | VAF 78/453 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as COSV64263240; called by muse, mutect2, varscan2
- HS6ST3 | c.631G>T p.D211Y | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100941319; called by muse, mutect2, varscan2
- HSP90B1 | c.2152T>C p.F718L | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.049); catalogued as COSV100236692; called by muse, mutect2
- HSPG2 | c.11602G>T p.V3868L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs368497178; called by muse, mutect2, varscan2
- HTR5A | c.41C>A p.T14N | Missense Mutation (SNP) | VAF 165/264 reads (63%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99839890; called by muse, mutect2, varscan2
- IFNA13 | c.457C>A p.L153I | Missense Mutation (SNP) | VAF 101/281 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as COSV101489509, COSV101489534; called by muse, mutect2, varscan2
- IGHV1-58 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs976574192; called by muse, mutect2, varscan2
- IGSF9B | c.1392G>T p.K464N | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.18); catalogued as COSV100318216; called by muse, mutect2, varscan2
- IL17REL | c.600C>A p.N200K | Missense Mutation (SNP) | VAF 77/219 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as COSV100377420; called by muse, mutect2, varscan2
- IPO8 | c.2726A>C p.N909T | Missense Mutation (SNP) | VAF 51/188 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99805558; called by muse, mutect2, varscan2
- IRF6 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.448); catalogued as COSV100884018; called by muse, mutect2, varscan2
- IRF6 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV65420140; called by muse, mutect2, varscan2
- ITGA4 | c.1886C>T p.A629V | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV51999611; called by muse, mutect2, varscan2
- ITIH5 | c.444del p.S149Afs*9 | Frame Shift Del (DEL) | VAF 20/67 reads (30%) | catalogued as COSV56900398, COSV56917083; called by mutect2, pindel, varscan2
- ITIH6 | c.2659C>A p.P887T | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as COSV99513770; called by muse, mutect2, varscan2
- ITPKB | c.641G>C p.G214A | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV99684920; called by muse, mutect2, varscan2
- ITPR1 | c.977G>T p.C326F | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV100232600; called by muse, mutect2, varscan2
- KCNH1 | c.2366C>A p.T789N (on ENST00000271751 / NM_172362.3; = p.T762N on NM_002238.4) | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.556); catalogued as COSV99660643; called by muse, mutect2, varscan2
- KDM6A | c.2988T>A p.H996Q | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV100938492; called by muse, mutect2, varscan2
- KEAP1 | c.851A>T p.Q284L | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV50260840; called by muse, mutect2, varscan2
- KIAA1210 | c.4390G>A p.A1464T | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV101274346; called by mutect2, varscan2
- KIAA1549L | c.71C>T p.S24L (on ENST00000321505; = p.S321L on NM_012194.3) | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV99684151; called by muse, mutect2
- KIF18A | c.391G>T p.G131* | Nonsense Mutation (SNP) | VAF 41/283 reads (14%) | catalogued as COSV99588989; called by muse, mutect2, varscan2
- KIF2B | c.1541C>T p.T514I | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99275951; called by muse, mutect2, varscan2
- KLF11 | c.1310G>T p.R437L | Missense Mutation (SNP) | VAF 77/128 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369814305; called by muse, mutect2, varscan2
- KLF12 | c.653G>T p.G218V | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV100888600; called by muse, mutect2, varscan2
- KLHDC4 | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 92/199 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.216); catalogued as COSV99566637; called by muse, mutect2, varscan2
- KRT83 | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV53342072; called by muse, mutect2, varscan2
- KRTAP10-4 | c.891C>G p.C297W | Missense Mutation (SNP) | VAF 92/281 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100554955; called by muse, mutect2, varscan2
- KRTAP5-5 | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.102); catalogued as rs1226604876, COSV101294201; called by muse, varscan2
- KRTAP5-5 | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.734); catalogued as rs1279012181, COSV68784404; called by muse, varscan2
- KYNU | c.812G>C p.C271S | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV99933721; called by muse, mutect2, varscan2
- LAD1 | c.926G>T p.R309I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); catalogued as COSV100943906; called by muse, mutect2, varscan2
- LAMA1 | c.3100G>T p.G1034C | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101057296; called by muse, mutect2, varscan2
- LAX1 | c.743G>C p.G248A | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs149181221; called by muse, mutect2, varscan2
- LCT | c.1798G>T p.V600L | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.895); catalogued as COSV99930155; called by muse, mutect2, varscan2
- LDLRAD4 | c.826C>A p.H276N | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV100762650; called by muse, mutect2, varscan2
- LHFPL1 | c.572G>A p.G191E | Missense Mutation (SNP) | VAF 62/151 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV100914502; called by muse, mutect2, varscan2
- LILRB2 | c.429G>T p.Q143H | Missense Mutation (SNP) | VAF 66/127 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.335); catalogued as rs757222116, COSV100079552; called by muse, mutect2, varscan2
- LILRB4 | c.528C>A p.H176Q | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.292); catalogued as COSV99554043; called by muse, mutect2, varscan2
- LINGO1 | c.1358C>A p.P453Q | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.35); PolyPhen benign (0.03); catalogued as rs568947342, COSV100796389, COSV100796473; called by muse, mutect2, varscan2
- LINGO2 | c.1652C>G p.T551R | Missense Mutation (SNP) | VAF 47/81 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV100431035; called by muse, mutect2, varscan2
- LMTK2 | c.194G>T p.C65F | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51996705, COSV99807472; called by muse, mutect2, varscan2
- LRCH3 | c.1690C>T p.H564Y | Missense Mutation (SNP) | VAF 27/225 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.309); catalogued as COSV100605204; called by muse, mutect2, varscan2
- LRIG3 | c.1123A>G p.I375V | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.965); catalogued as rs773148001, COSV57862430; called by muse, mutect2, varscan2
- LRP1B | c.8026G>T p.V2676F | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.694); catalogued as COSV101259237; called by muse, mutect2, varscan2
- LRP1B | c.7035G>C p.M2345I | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV101259239; called by muse, mutect2, varscan2
- LRRC7 | c.3312C>G p.I1104M (on ENST00000651989 / NM_001370785.2; = p.I1071M on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV99228797; called by muse, mutect2, varscan2
- LRRC7 | c.4270C>A p.L1424I (on ENST00000651989 / NM_001370785.2; = p.L1344I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.125); catalogued as COSV99228800; called by muse, mutect2, varscan2
- LRRN4 | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 81/247 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.183); catalogued as rs1242886001, COSV66644773; called by muse, mutect2, varscan2
- LRRTM3 | c.364T>A p.S122T | Missense Mutation (SNP) | VAF 81/169 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV100791835; called by muse, mutect2, varscan2
- LUZP2 | c.692C>G p.S231* | Nonsense Mutation (SNP) | VAF 34/237 reads (14%) | catalogued as rs1377740194, COSV100420901; called by muse, mutect2, varscan2
- LY75 | c.3572A>C p.N1191T | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.257); catalogued as rs746792872, COSV99716816; called by muse, mutect2, varscan2
- LY75-CD302 | c.5363C>T p.S1788F | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.702); catalogued as rs981055171, COSV99374608; called by muse, mutect2, varscan2
- LYST | c.3428G>T p.R1143M | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV101090065; called by muse, mutect2, varscan2
- LYZL1 | c.85G>T p.G29W | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV64966035; called by muse, mutect2, varscan2
- MADD | c.3146A>G p.Y1049C | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs374821739; called by muse, mutect2, varscan2
- MAGEB4 | c.98C>A p.A33E | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.477); catalogued as COSV100854769; called by muse, mutect2, varscan2
- MAGED2 | c.1234G>T p.V412L | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.138); catalogued as COSV99514703; called by muse, mutect2, varscan2
- MAGI3 | c.2437G>A p.G813R | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV100289994; called by muse, mutect2, varscan2
- MAML2 | c.3423C>G p.D1141E | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101594168; called by mutect2, varscan2
- MAN1A1 | c.110G>T p.R37L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100870414; called by muse, mutect2, varscan2
- MAOA | c.1036C>A p.L346M | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV100108944; called by muse, mutect2, varscan2
- MAOB | c.946A>G p.I316V | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as rs1174652648, COSV100956194; called by muse, mutect2, varscan2
- MATK | c.1246G>T p.E416* (on ENST00000310132 / NM_139355.3; = p.E417* on NM_002378.4) | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as COSV100036219; called by muse, mutect2, varscan2
- MBD5 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as rs1348400494, COSV101290218; called by muse, mutect2, varscan2
- MBD5 | c.4342G>A p.G1448R | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.992); catalogued as COSV101290219; called by muse, mutect2, varscan2
- MCF2L | c.1229C>T p.A410V (on ENST00000375608; = p.A378V on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0.314); catalogued as COSV100982795; called by muse, mutect2, varscan2
- MCMDC2 | c.1757C>T p.A586V | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs1327275593, COSV100552230; called by muse, mutect2, varscan2
- MCTP1 | c.880G>C p.E294Q | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.999); catalogued as COSV100387827, COSV56514376, COSV56536253; called by muse, mutect2
- MED12 | c.4320G>C p.Q1440H | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV100379344, COSV61336041; called by muse, mutect2, varscan2
- MEGF6 | c.4456G>C p.D1486H | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); catalogued as COSV99621041; called by muse, mutect2, varscan2
- METTL25 | c.848G>C p.G283A | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.254); catalogued as COSV99942603; called by muse, mutect2, varscan2
- MFAP3L | c.421C>G p.R141G | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100852704; called by muse, mutect2, varscan2
- MFN2 | c.1717-2A>G p.X573_splice | Splice Site (SNP) | VAF 21/83 reads (25%) | catalogued as COSV99336961; called by muse, mutect2, varscan2
- MIA2 | c.1798G>T p.D600Y | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs923356072, COSV54492180; called by muse, mutect2, varscan2
- MICAL1 | c.916C>A p.L306M | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); catalogued as COSV100668690; called by muse, mutect2, varscan2
- MID2 | c.1139A>C p.E380A | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as COSV99465349; called by muse, mutect2, varscan2
- MME | c.1095-1G>A p.X365_splice | Splice Site (SNP) | VAF 38/185 reads (21%) | catalogued as COSV64706044; called by muse, mutect2, varscan2
- MMRN1 | c.2186A>G p.N729S | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99307541; called by muse, mutect2, varscan2
- MNDA | c.500C>A p.S167Y | Missense Mutation (SNP) | VAF 47/277 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.177); catalogued as COSV63740579; called by muse, mutect2, varscan2
- MRC2 | c.1639C>G p.R547G | Missense Mutation (SNP) | VAF 77/214 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV100316597; called by muse, mutect2, varscan2
- MRPL32 | c.98A>G p.Q33R | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV99785959; called by muse, mutect2, varscan2
- MS4A14 | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.524); catalogued as rs1258544246, COSV100280588, COSV100280653; called by muse, mutect2, varscan2
- MSH5 | c.1074G>T p.Q358H | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV100994948; called by muse, mutect2, varscan2
- MSI2 | c.859G>T p.G287C | Missense Mutation (SNP) | VAF 37/229 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99403198; called by muse, mutect2, varscan2
- MTNR1B | c.361G>A p.G121S | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.897); catalogued as COSV57066920, COSV99925256; called by muse, mutect2, varscan2
- MUC16 | c.22837C>A p.L7613M | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV101200750; called by muse, mutect2, varscan2
- MUC16 | c.17552C>A p.P5851H | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); catalogued as COSV101200752, COSV67494343; called by muse, mutect2
- MUC3A | c.8914C>A p.L2972I | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.003); catalogued as rs1380346111, COSV100113851, COSV100115127; called by muse, mutect2, varscan2
- MUC5AC | c.1668C>G p.F556L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.03); catalogued as COSV100650498, COSV100650522, COSV100650659; called by muse, mutect2, varscan2
- MUC7 | c.88C>A p.R30S | Missense Mutation (SNP) | VAF 31/187 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as rs780124896, COSV100512361; called by muse, mutect2, varscan2
- MXRA5 | c.5561A>T p.Q1854L | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.233); catalogued as COSV99478514; called by muse, mutect2, varscan2
- MYBPC1 | c.200G>T p.G67V (on ENST00000550270 / NM_206820.2; = p.G92V on NM_002465.4) | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.867); catalogued as COSV100638208; called by muse, mutect2, varscan2
- MYH7 | c.4293C>A p.D1431E | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as rs45560242, COSV100806441; called by muse, mutect2, varscan2
- MYLK | c.2816C>G p.S939C | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.353); catalogued as COSV100659428; called by muse, mutect2, varscan2
- MYO18B | c.2674G>C p.E892Q | Missense Mutation (SNP) | VAF 55/262 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as COSV100124602, COSV59138938; called by muse, mutect2, varscan2
- MYO6 | c.1829G>T p.C610F | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.699); catalogued as COSV100889397; called by muse, mutect2, varscan2
- MYPN | c.1899C>A p.N633K | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as COSV62734719; called by muse, mutect2, varscan2
- N4BP2L2 | c.794G>T p.R265M | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV99912667; called by muse, mutect2, varscan2
- NALCN | c.3519A>C p.R1173S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV99216905; called by muse, mutect2, varscan2
- NALCN | c.147C>A p.S49R | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99216909; called by muse, mutect2, varscan2
- NAP1L3 | c.1433T>A p.L478Q | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.269); catalogued as COSV100220576; called by muse, mutect2, varscan2
- NCOA2 | c.3947C>G p.T1316S | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.551); catalogued as COSV99144962, COSV99145001; called by muse, mutect2, varscan2
- NELFB | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.053); catalogued as COSV100546998; called by muse, mutect2, varscan2
- NELL1 | c.1515A>T p.K505N | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.119); catalogued as COSV100123672; called by muse, mutect2, varscan2
- NELL1 | c.2224G>T p.E742* | Nonsense Mutation (SNP) | VAF 33/205 reads (16%) | catalogued as COSV100123674; called by muse, mutect2, varscan2
- NF1 | c.8479G>C p.A2827P (on ENST00000358273 / NM_001042492.3; = p.A2806P on NM_000267.3) | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.358); catalogued as COSV100647928, COSV99049866; called by muse, mutect2, varscan2
- NFATC4 | c.2282G>T p.G761V | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV99149061; called by muse, mutect2, varscan2
- NIPSNAP3A | c.700C>G p.Q234E | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.065); catalogued as COSV101044518; called by muse, mutect2, varscan2
- NLGN1 | c.311G>T p.W104L | Missense Mutation (SNP) | VAF 40/483 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100849829; called by muse, mutect2
- NMBR | c.1049G>T p.G350V | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV99237430; called by muse, mutect2, varscan2
- NOL11 | c.1907C>G p.P636R | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.946); catalogued as COSV99475232; called by muse, mutect2, varscan2
- NOS1 | c.2742G>T p.E914D | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100500750, COSV100501158; called by muse, mutect2, varscan2
- NOTCH4 | c.5929G>C p.E1977Q | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.81); catalogued as COSV66679314, COSV66679913; called by muse, mutect2, varscan2
- NOX3 | c.894G>T p.V298= | Splice Region (SNP) | VAF 39/83 reads (47%) | catalogued as COSV99343546; called by muse, mutect2, varscan2
- NPAP1 | c.2855A>G p.Y952C | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.633); catalogued as rs1001161563, COSV100275877; called by muse, mutect2, varscan2
- NPAS3 | c.766G>C p.D256H (on ENST00000356141 / NM_001164749.2; = p.D224H on NM_022123.3) | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.843); catalogued as COSV100640504; called by muse, mutect2, varscan2
- NR2E1 | c.620C>A p.S207Y | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.332); catalogued as COSV100934615; called by muse, mutect2, varscan2
- NUMA1 | c.2200C>T p.R734C | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV61188160; called by muse, mutect2, varscan2
- NUP58 | c.1180C>G p.Q394E | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0.059); catalogued as COSV101098869; called by muse, mutect2, varscan2
- NXPE4 | c.179T>C p.I60T | Missense Mutation (SNP) | VAF 7/180 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV100970532; called by muse, mutect2
- OGFR | c.1414G>T p.A472S | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.145); catalogued as rs986789982, COSV99284382; called by muse, mutect2, varscan2
- OGT | c.2647G>C p.E883Q | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65479573, COSV65482772; called by muse, mutect2, varscan2
- OR10AG1 | c.131C>A p.P44H | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV56633003; called by muse, mutect2, varscan2
- OR10G8 | c.802G>T p.D268Y | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); catalogued as COSV101461861, COSV70908923; called by muse, mutect2, varscan2
- OR10J1 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 80/213 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101419940; called by muse, mutect2, varscan2
- OR10V1 | c.278T>C p.V93A | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV100276174; called by muse, mutect2, varscan2
- OR13A1 | c.750G>T p.W250C | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100981075; called by muse, mutect2, varscan2
- OR2T34 | c.289A>G p.I97V | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV100170479; called by muse, mutect2, varscan2
- OR4A15 | c.723C>A p.H241Q | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs774389659, COSV100123923; called by muse, mutect2, varscan2
- OR4C13 | c.715G>T p.V239F | Missense Mutation (SNP) | VAF 91/200 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.595); catalogued as rs1555015881, COSV101634215, COSV101634240; called by muse, mutect2, varscan2
- OR4C46 | c.62T>C p.M21T | Missense Mutation (SNP) | VAF 73/191 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.006); catalogued as rs373356728, COSV60220018; called by muse, mutect2, varscan2
- OR4S1 | c.97C>A p.H33N | Missense Mutation (SNP) | VAF 48/305 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV100180311; called by muse, mutect2, varscan2
- OR51V1 | c.344C>A p.S115Y | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100343458, COSV58315757; called by muse, mutect2, varscan2
- OR5H2 | c.626G>T p.G209V | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV62351373; called by muse, mutect2, varscan2
- OR5L1 | c.212T>G p.F71C | Missense Mutation (SNP) | VAF 63/194 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV100450172; called by muse, mutect2, varscan2
- OR5T1 | c.562C>G p.H188D | Missense Mutation (SNP) | VAF 94/286 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100479160, COSV57301712, COSV57304173; called by muse, mutect2
- OR8B12 | c.479G>T p.G160V | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.25); catalogued as COSV100172889, COSV60911470; called by muse, mutect2, varscan2
- OR8H2 | c.388C>A p.L130I | Missense Mutation (SNP) | VAF 33/217 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100542438; called by muse, mutect2, varscan2
- OR8I2 | c.716C>A p.T239N | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100136217; called by muse, mutect2, varscan2
- OR9G4 | c.197T>C p.L66P | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100265222; called by muse, mutect2, varscan2
- P3H1 | c.1495G>A p.G499S | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.788); catalogued as COSV99355470; called by muse, mutect2, varscan2
- PAH | c.1316G>C p.S439T | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV100188338; called by muse, mutect2, varscan2
- PAPPA2 | c.3043G>T p.G1015W | Missense Mutation (SNP) | VAF 88/221 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV100868443, COSV62802985; called by muse, varscan2
- PCCA | c.667G>T p.G223C | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100887009; called by muse, mutect2, varscan2
- PCDH11X | c.1850C>G p.T617S | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.023); catalogued as COSV100014030, COSV53470605; called by muse, mutect2, varscan2
- PCDH11X | c.3075G>T p.E1025D | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.048); catalogued as COSV100014040; called by muse, mutect2, varscan2
- PCDH17 | c.2044C>A p.R682S | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT tolerated (0.8); PolyPhen benign (0.176); catalogued as COSV64972073; called by muse, mutect2, varscan2
- PCDHGA3 | c.854C>A p.P285H | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.049); catalogued as COSV99543889; called by muse, mutect2, varscan2
- PCDHGA9 | c.24G>T p.Q8H | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV99543892; called by muse, mutect2, varscan2
- PCOLCE2 | c.971C>A p.T324K | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as COSV56003052, COSV99930675; called by muse, mutect2, varscan2
- PDCD6IP | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as COSV100219065; called by muse, mutect2, varscan2
- PER1 | c.2299G>T p.D767Y | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100424772; called by muse, mutect2, varscan2
- PEX11A | c.233C>T p.T78I | Missense Mutation (SNP) | VAF 48/86 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs1224442931, COSV100261655; called by muse, mutect2, varscan2
- PGR | c.1763A>T p.K588M | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99678884; called by muse, mutect2, varscan2
- PHEX | c.161G>A p.C54Y | Missense Mutation (SNP) | VAF 62/299 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101039913; called by muse, mutect2, varscan2
- PHKG1 | c.202C>G p.R68G | Missense Mutation (SNP) | VAF 38/62 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); catalogued as COSV52079575, COSV99818338; called by muse, mutect2, varscan2
- PIAS4 | c.1384G>A p.G462S | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV99519003; called by muse, mutect2, varscan2
- PIDD1 | c.800G>T p.R267L | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.592); catalogued as COSV100758740; called by muse, mutect2, varscan2
- PIGA | c.1083G>T p.K361N | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV100363499; called by muse, mutect2, varscan2
- PIGO | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057180311, COSV99956878; ClinVar: uncertain significance; called by muse, mutect2
- PIK3CA | c.250G>C p.D84H | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55899576, COSV99841761; called by muse, mutect2, varscan2
- PKD2 | c.1310G>T p.C437F | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99417686; called by muse, mutect2, varscan2
- PKD2L1 | c.1720C>G p.Q574E | Missense Mutation (SNP) | VAF 64/118 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as COSV100559422; called by muse, mutect2, varscan2
- PKHD1L1 | c.7784C>A p.P2595Q | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV101006632; called by muse, mutect2, varscan2
- PKHD1L1 | c.11717C>A p.T3906N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV101006633; called by muse, mutect2, varscan2
- PLCB1 | c.2080G>T p.G694W | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100571802; called by muse, mutect2, varscan2
- PLCB2 | c.917A>T p.D306V | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV99542447; called by muse, mutect2, varscan2
- PLCL1 | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.755); catalogued as COSV101406880; called by muse, mutect2, varscan2
- PLCL1 | c.2494G>C p.V832L | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV101407237; called by muse, mutect2, varscan2
- PLCZ1 | c.82C>A p.L28I | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV99856733; called by muse, mutect2, varscan2
- PLEC | c.835C>G p.L279V (on ENST00000322810 / NM_201380.4; = p.L169V on NM_000445.5) | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV59634419; called by muse, mutect2, varscan2
- POLR3B | c.1193C>A p.A398D | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as COSV99943756; called by muse, mutect2, varscan2
- POLR3K | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.162); catalogued as COSV99244484, COSV99244998; called by muse, mutect2, varscan2
- POMK | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 56/115 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as rs749227228, COSV100505956; called by muse, mutect2, varscan2
- POPDC2 | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 93/180 reads (52%) | catalogued as COSV99951114; called by muse, mutect2, varscan2
- POTEH | c.511C>G p.H171D | Missense Mutation (SNP) | VAF 30/203 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.164); catalogued as COSV100625135; called by muse, mutect2, varscan2
- POU4F3 | c.497C>A p.T166N | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV100047208; called by muse, mutect2, varscan2
- PPP2R2C | c.277A>T p.N93Y | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100067086; called by muse, mutect2, varscan2
- PPRC1 | c.1657G>T p.G553C | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs746746156, COSV99531927; called by muse, mutect2, varscan2
- PPTC7 | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as COSV100845727; called by muse, mutect2, varscan2
- PROX1 | c.1126T>G p.S376A | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV99799992; called by muse, mutect2, varscan2
- PRR30 | c.462C>A p.S154R | Missense Mutation (SNP) | VAF 58/92 reads (63%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.555); catalogued as COSV99574725; called by muse, mutect2, varscan2
- PRSS33 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99550140; called by muse, mutect2, varscan2
- PTCHD1 | c.2050C>T p.P684S | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as COSV101037928; called by muse, mutect2, varscan2
- PTPRK | c.958G>C p.D320H | Missense Mutation (SNP) | VAF 47/219 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100949675; called by muse, mutect2, varscan2
- PTPRU | c.1869-1G>T p.X623_splice | Splice Site (SNP) | VAF 7/31 reads (23%) | catalogued as COSV100113483; called by muse, mutect2
- PTPRZ1 | c.716C>A p.P239H | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101100614, COSV66445077; called by muse, mutect2, varscan2
- PTPRZ1 | c.6228C>A p.D2076E | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101100616; called by muse, mutect2, varscan2
- R3HCC1L | c.955G>C p.E319Q | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); catalogued as COSV100107484; called by muse, mutect2, varscan2
- RAD54L | c.1610G>A p.R537K | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.77); PolyPhen benign (0.011); catalogued as COSV100586527; called by muse, mutect2
- RAI14 | c.49A>G p.N17D | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99464196; called by muse, mutect2, varscan2
- RALA | c.289G>C p.E97Q | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.871); catalogued as COSV99143447; called by muse, mutect2, varscan2
- RARG | c.244C>G p.P82A | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as COSV100553625, COSV58432727; called by muse, mutect2, varscan2
- RFPL3 | c.898C>T p.P300S (on ENST00000249007 / NM_001098535.1; = p.P271S on NM_006604.2) | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.936); catalogued as COSV99967222; called by muse, mutect2, varscan2
- RGS18 | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.864); catalogued as COSV100817866; called by muse, mutect2, varscan2
- RGS4 | c.500G>C p.R167P | Missense Mutation (SNP) | VAF 155/370 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100905595, COSV63357266, COSV63357554; called by muse, mutect2, varscan2
- RGS7BP | c.651G>T p.R217S | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV100471153, COSV61835572; called by muse, mutect2, varscan2
- RIMBP2 | c.2339G>T p.G780V | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.035); catalogued as COSV99900132; called by muse, mutect2, varscan2
- RNF144B | c.479G>T p.W160L | Missense Mutation (SNP) | VAF 85/466 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99464931; called by muse, varscan2
- RNMT | c.840C>G p.I280M | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV100054818; called by muse, mutect2, varscan2
- ROBO1 | c.1966G>T p.D656Y | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101459126; called by muse, mutect2, varscan2
- ROBO3 | c.1303G>T p.A435S | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV101185144; called by muse, mutect2, varscan2
- ROGDI | c.373T>G p.Y125D | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0.185); catalogued as COSV100424465; called by muse, mutect2, varscan2
- ROS1 | c.3508G>T p.D1170Y | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100877550; called by muse, mutect2, varscan2
- RP1 | c.6190G>T p.A2064S | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.75); PolyPhen benign (0.014); catalogued as rs1330153982, COSV99608396; called by muse, mutect2, varscan2
- RTL9 | c.1760C>T p.S587L | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.036); catalogued as COSV101511765; called by muse, varscan2
- RUNX1T1 | c.1166T>C p.L389S (on ENST00000265814 / NM_001198628.1; = p.L362S on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99753934; called by muse, mutect2, varscan2
- RYR2 | c.1394C>G p.P465R | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.069); catalogued as COSV100772123; called by muse, mutect2, varscan2
- RYR2 | c.10979G>A p.R3660K | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100772124, COSV63658499, COSV63665973; called by muse, mutect2, varscan2
- RYR2 | c.13705G>C p.E4569Q | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.056); catalogued as rs1319611231, COSV100769885, COSV100772126; called by muse, mutect2, varscan2
- RYR3 | c.13691T>A p.L4564H (on ENST00000389232; = p.L4565H on NM_001036.6) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.956); catalogued as COSV101213642; called by muse, mutect2, varscan2
- SAMD3 | c.259G>T p.A87S | Missense Mutation (SNP) | VAF 61/181 reads (34%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV100148163, COSV100148364; called by muse, mutect2, varscan2
- SBNO2 | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); catalogued as rs1319227183, COSV62322605; called by muse, mutect2, varscan2
- SBSN | c.338A>G p.E113G | Missense Mutation (SNP) | VAF 56/383 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV101510096; called by muse, mutect2, varscan2
- SCAF4 | c.1553G>C p.R518T | Missense Mutation (SNP) | VAF 5/102 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV54589799, COSV99741924; called by muse, mutect2
- SCG2 | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 112/321 reads (35%) | catalogued as COSV100544846; called by muse, mutect2, varscan2
- SCN11A | c.1666G>T p.V556L | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV100182151; called by muse, mutect2, varscan2
- SEC24B | c.286A>G p.T96A | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV99494099; called by muse, mutect2, varscan2
- SEMA5B | c.3297+2T>C p.X1099_splice | Splice Site (SNP) | VAF 33/61 reads (54%) | catalogued as COSV99532836; called by muse, mutect2, varscan2
- SEMA6D | c.3037C>T p.Q1013* (on ENST00000316364 / NM_153618.2; = p.Q951* on NM_020858.2) | Nonsense Mutation (SNP) | VAF 36/169 reads (21%) | catalogued as COSV60386855; called by muse, mutect2, varscan2
- SENP6 | c.986A>T p.N329I | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100519445; called by muse, mutect2, varscan2
- SEPTIN3 | c.630C>A p.D210E | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99352303; called by muse, varscan2
- SEPTIN8 | c.1150G>T p.V384L | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99736539; called by muse, mutect2, varscan2
- SF1 | c.1609G>A p.G537S | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.098); catalogued as COSV99918640; called by muse, mutect2, varscan2
- SGK2 | c.829T>C p.W277R | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100414791; called by muse, mutect2, varscan2
- SHROOM4 | c.3134C>G p.S1045C | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.257); catalogued as COSV99174141; called by muse, mutect2
- SIDT2 | c.159C>A p.F53L | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV54054697, COSV99638236; called by muse, mutect2, varscan2
- SIGLEC14 | c.955T>A p.C319S | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99707787; called by muse, mutect2, varscan2
- SIRPB2 | c.145C>A p.L49M | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.958); catalogued as COSV100708592; called by muse, mutect2, varscan2
- SIRPG | c.451G>T p.V151L | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as COSV99403893; called by muse, mutect2, varscan2
- SIRPG | c.94C>G p.L32V | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV99403895; called by muse, mutect2, varscan2
- SLC22A9 | c.1271T>C p.I424T | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0.058); catalogued as COSV99655288; called by muse, mutect2, varscan2
- SLC24A1 | c.3079C>G p.L1027V | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.19); catalogued as rs915861732, COSV99978537; called by muse, mutect2, varscan2
- SLC26A3 | c.610T>A p.Y204N | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM115265, COSV100385247; called by muse, mutect2, varscan2
- SLC35C1 | c.75G>C p.E25D | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV100029452, COSV58479803; called by muse, mutect2, varscan2
- SLC35F5 | c.479T>G p.L160W | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99830165; called by muse, mutect2, varscan2
- SLC39A12 | c.519G>T p.Q173H | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV101070106; called by muse, mutect2, varscan2
- SLC46A3 | c.1223C>T p.S408L | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV99906468; called by muse, mutect2, varscan2
- SLC6A7 | c.644G>T p.W215L | Missense Mutation (SNP) | VAF 49/89 reads (55%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.893); catalogued as COSV100045939; called by muse, mutect2, varscan2
- SMC4 | c.3253G>A p.E1085K | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as COSV59086721; called by muse, mutect2
- SMC5 | c.3058G>A p.E1020K | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100747143, COSV63191732; called by muse, mutect2, varscan2
- SMPD4 | c.1877G>T p.W626L (on ENST00000409031 / NM_017951.4; = p.W597L on NM_017751.4) | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as COSV100302665, COSV60082673; called by muse, mutect2, varscan2
- SNAP47 | c.1051G>C p.E351Q | Missense Mutation (SNP) | VAF 42/224 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.943); catalogued as COSV100248377; called by muse, mutect2, varscan2
- SOCS7 | c.1591C>T p.R531C | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as rs764623857; called by muse, mutect2, varscan2
- SPEF2 | c.1317G>T p.L439F | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.676); catalogued as rs571409302, COSV99214681; called by muse, mutect2, varscan2
- SPEF2 | c.4026T>G p.N1342K | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.014); catalogued as COSV100608415; called by muse, mutect2, varscan2
- SPEF2 | c.5109G>T p.R1703S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.69); PolyPhen benign (0.144); catalogued as COSV100289292, COSV57429268; called by muse, mutect2, varscan2
- SPESP1 | c.407A>G p.E136G | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.152); catalogued as COSV99534499; called by muse, mutect2, varscan2
- SPICE1 | c.335C>G p.S112C | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55624862, COSV99871635; called by muse, mutect2, varscan2
- SPOCK1 | c.327C>A p.S109R | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV99970418; called by muse, mutect2, varscan2
- SRPX2 | c.1159C>A p.Q387K | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100884049; called by muse, mutect2, varscan2
- SSMEM1 | c.215G>C p.G72A | Missense Mutation (SNP) | VAF 57/110 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as COSV99927815; called by muse, mutect2, varscan2
- SSTR1 | c.661G>T p.V221L | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as rs1259288631, COSV99943040; called by muse, mutect2, varscan2
- SSTR4 | c.400G>A p.V134I | Missense Mutation (SNP) | VAF 55/249 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as rs750847560, COSV54799603; called by muse, mutect2, varscan2
- ST8SIA5 | c.312-1G>T p.X104_splice | Splice Site (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100164618, COSV100164875; called by muse, mutect2, varscan2
- STAC3 | c.432+2T>C p.X144_splice | Splice Site (SNP) | VAF 134/724 reads (19%) | catalogued as rs776763306, COSV100234687; called by muse, mutect2, varscan2
- STAP1 | c.429G>T p.E143D | Missense Mutation (SNP) | VAF 60/159 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99609592; called by muse, mutect2, varscan2
- STX5 | c.296+1G>T p.X99_splice | Splice Site (SNP) | VAF 20/117 reads (17%) | catalogued as COSV99587024; called by muse, mutect2, varscan2
- SYNE1 | c.22274A>T p.K7425M (on ENST00000367255 / NM_182961.4; = p.K7354M on NM_033071.3) | Missense Mutation (SNP) | VAF 56/115 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); catalogued as rs781161322, COSV99574399; called by muse, mutect2, varscan2
- SYNE2 | c.16851A>T p.K5617N | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.147); catalogued as COSV100648264; called by muse, mutect2, varscan2
- SYT4 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV54898278; called by muse, mutect2, varscan2
- SYTL4 | c.1272T>A p.Y424* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as COSV99343208; called by mutect2, varscan2
- TAF1 | c.911C>G p.S304* (on ENST00000373790 / NM_138923.4; = p.S325* on NM_004606.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 17/100 reads (17%) | catalogued as COSV99336601; called by muse, mutect2, varscan2
- TAF1L | c.4132G>C p.G1378R | Missense Mutation (SNP) | VAF 138/223 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.13); catalogued as COSV99645213; called by muse, mutect2, varscan2
- TAS2R1 | c.858A>T p.Q286H | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as COSV101225831; called by muse, mutect2, varscan2
- TAS2R13 | c.912A>G p.*304Wext*27 | Nonstop Mutation (SNP) | VAF 40/127 reads (31%) | catalogued as COSV101183760, COSV66831758; called by muse, mutect2, varscan2
- TBC1D25 | c.1093A>T p.N365Y | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100952202; called by muse, mutect2, varscan2
- TBRG4 | c.220C>A p.H74N | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99345582; called by muse, mutect2, varscan2
- TCEAL4 | c.311G>A p.G104E | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.096); catalogued as rs1417774278, COSV101010283; called by muse, mutect2
- TFAP2D | c.1082C>A p.S361Y | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99146729; called by muse, mutect2, varscan2
- THG1L | c.574G>T p.A192S | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as COSV99180277; called by muse, mutect2, varscan2
- TIGD3 | c.1102G>T p.G368C | Missense Mutation (SNP) | VAF 66/201 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV52888842, COSV99361839; called by muse, mutect2, varscan2
- TKTL2 | c.1124G>A p.S375N | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.097); catalogued as COSV99761641; called by muse, mutect2, varscan2
- TLL2 | c.1339A>T p.S447C | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100780401; called by muse, mutect2, varscan2
- TLR10 | c.670G>T p.G224C | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.571); catalogued as COSV100457931; called by muse, mutect2, varscan2
- TLR4 | c.839T>A p.L280Q (on ENST00000355622 / NM_138554.5; = p.L240Q on NM_003266.4) | Missense Mutation (SNP) | VAF 90/156 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100790681, COSV62923900; called by muse, mutect2, varscan2
- TMEM217 | c.335A>G p.Q112R | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.929); catalogued as COSV100362654; called by muse, mutect2, varscan2
- TMEM38B | c.160G>T p.A54S | Missense Mutation (SNP) | VAF 66/108 reads (61%) | SIFT tolerated (0.25); PolyPhen benign (0.416); catalogued as rs369394875; called by muse, mutect2, varscan2
- TMUB2 | c.200T>G p.L67R (on ENST00000538716 / NM_001353177.2; = p.L47R on NM_024107.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/181 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100116287; called by muse, mutect2, varscan2
- TOPBP1 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV99605680; called by muse, mutect2, varscan2
- TRIM3 | c.353A>G p.H118R | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100624505; called by muse, mutect2
- TRIM71 | c.794T>A p.F265Y | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.899); catalogued as COSV101070480; called by muse, mutect2, varscan2
- TRIM8 | c.698G>T p.R233L | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV100193372; called by muse, mutect2, varscan2
- TRIOBP | c.2534G>T p.R845I | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); catalogued as COSV100731044; called by muse, mutect2, varscan2
- TRMT61A | c.668G>T p.R223L | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV100149427; called by muse, mutect2, varscan2
- TRPA1 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as COSV100084865; called by muse, mutect2, varscan2
- TRPM7 | c.2026T>G p.S676A | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV100540184; called by muse, mutect2, varscan2
- TRPV2 | c.2116G>T p.V706L | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100641326; called by muse, mutect2, varscan2
- TSKU | c.512G>C p.R171P | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.194); catalogued as COSV100290197; called by muse, mutect2, varscan2
- TSNARE1 | c.1290G>A p.E430= | Splice Region (SNP) | VAF 8/62 reads (13%) | catalogued as COSV100211190; called by muse, mutect2, varscan2
- TTN | c.50129C>A p.A16710D (on ENST00000591111; = p.A9286D on NM_003319.4) | Missense Mutation (SNP) | VAF 20/109 reads (18%) | PolyPhen probably damaging (0.999); catalogued as COSV100623918; called by muse, mutect2, varscan2
- TTN | c.36080C>A p.P12027H (on ENST00000591111; = p.P4603H on NM_003319.4) | Missense Mutation (SNP) | VAF 16/42 reads (38%) | PolyPhen probably damaging (0.988); catalogued as COSV100623921; called by muse, mutect2, varscan2
- TTN | c.36079C>A p.P12027T (on ENST00000591111; = p.P4603T on NM_003319.4) | Missense Mutation (SNP) | VAF 16/41 reads (39%) | PolyPhen probably damaging (0.91); catalogued as COSV100623922; called by muse, mutect2, varscan2
- TTN | c.15760C>A p.P5254T (on ENST00000591111; = p.P4327T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/189 reads (16%) | PolyPhen probably damaging (0.999); catalogued as COSV100623924, COSV60176740; called by muse, mutect2, varscan2
- TXNRD1 | c.103C>A p.H35N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.014); catalogued as COSV101423706; called by muse, mutect2, varscan2
- UBQLN2 | c.981G>T p.Q327H | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.719); catalogued as COSV100592779; called by muse, mutect2, varscan2
- UBR1 | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.058); catalogued as rs1387789565, COSV51926439, COSV99316642; called by muse, mutect2, varscan2
- UGT2B11 | c.819C>G p.N273K | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101485279; called by muse, mutect2, varscan2
- UNC45B | c.863G>A p.S288N | Missense Mutation (SNP) | VAF 131/299 reads (44%) | SIFT tolerated (0.76); PolyPhen benign (0.006); catalogued as COSV99269040; called by muse, mutect2, varscan2
- UNC5A | c.1846C>A p.H616N | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99459108; called by muse, varscan2
- UNC79 | c.3205G>T p.V1069L (on ENST00000393151 / NM_001346218.2; = p.V892L on NM_020818.5) | Missense Mutation (SNP) | VAF 47/194 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.375); catalogued as COSV99829306; called by muse, mutect2, varscan2
- UPP1 | c.730G>T p.V244F | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100080835; called by muse, mutect2, varscan2
- USH2A | c.4858C>T p.Q1620* | Nonsense Mutation (SNP) | VAF 61/174 reads (35%) | catalogued as COSV100239872; called by muse, mutect2, varscan2
- USP51 | c.265C>G p.L89V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV101540687; called by muse, mutect2, varscan2
- VEZT | c.224A>T p.Q75L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV99704192; called by muse, mutect2, varscan2
- VPS13A | c.1901-2A>C p.X634_splice | Splice Site (SNP) | VAF 37/83 reads (45%) | catalogued as COSV100653253; called by muse, mutect2, varscan2
- WDFY1 | c.1228C>T p.H410Y | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV99239549; called by muse, mutect2, varscan2
- WDR36 | c.2057T>A p.L686H | Missense Mutation (SNP) | VAF 57/117 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101550993; called by muse, mutect2, varscan2
- WDR89 | c.662G>T p.C221F | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV99962539; called by muse, mutect2, varscan2
- WNK2 | c.4840G>T p.E1614* (on ENST00000297954 / NM_001282394.1; = p.E1577* on NM_006648.3) | Nonsense Mutation (SNP) | VAF 12/23 reads (52%) | catalogued as COSV99943957; called by muse, mutect2, varscan2
- WNT2 | c.323C>A p.S108Y | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV99626293; called by muse, mutect2, varscan2
- WSCD2 | c.1152A>T p.K384N | Missense Mutation (SNP) | VAF 62/237 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV99775048; called by muse, mutect2, varscan2
- XIRP2 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.555); catalogued as rs1175742929, COSV54683865, COSV54731845; called by muse, mutect2, varscan2
- XKR3 | c.96C>G p.S32R | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV100509346; called by muse, mutect2, varscan2
- XPNPEP2 | c.79G>T p.D27Y | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV100941278; called by muse, mutect2, varscan2
- XRCC1 | c.1870C>G p.H624D | Missense Mutation (SNP) | VAF 10/233 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV53447006, COSV99486665; called by muse, mutect2
- YIPF7 | c.203A>G p.E68G | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100274604; called by muse, varscan2
- YIPF7 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV100274606; called by muse, varscan2
- ZC3H12B | c.1819G>A p.D607N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as rs756432317, COSV100161898; called by muse, mutect2, varscan2
- ZC3H7B | c.2648G>T p.R883L | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60960280; called by muse, mutect2, varscan2
- ZDBF2 | c.7046G>A p.R2349K | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100985275, COSV65624347; called by muse, mutect2
- ZDHHC15 | c.219G>C p.W73C | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs775404497, COSV100973829; called by muse, mutect2, varscan2
- ZER1 | c.2228C>A p.T743N | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV99402318; called by muse, mutect2, varscan2
- ZFHX4 | c.3682G>T p.D1228Y | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99257402, COSV99266113; called by muse, mutect2, varscan2
- ZNF195 | c.1420G>A p.V474I (on ENST00000399602 / NM_001130520.3; = p.V402I on NM_007152.5) | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs751311312, COSV99138103; called by muse, mutect2, varscan2
- ZNF25 | c.101A>T p.K34M | Missense Mutation (SNP) | VAF 66/126 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV100224734; called by muse, mutect2, varscan2
- ZNF280A | c.464G>T p.G155V | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100131195; called by muse, mutect2, varscan2
- ZNF354A | c.1463A>T p.H488L | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100234594; called by muse, mutect2, varscan2
- ZNF44 | c.958G>A p.E320K (on ENST00000356109 / NM_001164276.2; = p.E272K on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.095); catalogued as COSV100633649; called by muse, mutect2, varscan2
- ZNF682 | c.1466C>G p.A489G | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as COSV100653331; called by muse, mutect2, varscan2
- ZNF804B | c.1151T>A p.L384Q | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV100305305; called by muse, mutect2, varscan2
- ZNF804B | c.2881G>T p.V961F | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.035); catalogued as COSV100305306; called by muse, mutect2, varscan2
- ZNF816 | c.1247G>A p.R416K | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as COSV54411846, COSV99554671; called by muse, mutect2, varscan2
- ZNF816 | c.934C>A p.P312T | Missense Mutation (SNP) | VAF 32/248 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV54413405; called by muse, mutect2, varscan2
- ZNF92 | c.43C>G p.L15V | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.986); catalogued as COSV60876045; called by muse, mutect2, varscan2
- ZSWIM2 | c.691G>T p.G231W | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99720149; called by muse, mutect2, varscan2
- ZYG11B | c.1402G>T p.A468S | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.221); catalogued as COSV99597709; called by muse, mutect2, varscan2
- ATP10D | c.1518del p.N506Kfs*19 | Frame Shift Del (DEL) | VAF 11/98 reads (11%) | called by mutect2, pindel*, varscan2
- CGNL1 | c.3350_3361del p.C1117_I1120del | In Frame Del (DEL) | VAF 19/90 reads (21%) | called by mutect2, pindel, varscan2
- CIPC | c.1169del p.L390Qfs*20 | Frame Shift Del (DEL) | VAF 49/132 reads (37%) | called by mutect2, pindel, varscan2
- DHX37 | c.1002_1004del p.Y335del | In Frame Del (DEL) | VAF 43/158 reads (27%) | called by mutect2, pindel, varscan2
- EBF2 | c.1538C>A p.S513* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | called by mutect2, varscan2
- GPR179 | c.1364T>A p.L455Q (on ENST00000621958; = p.L454Q on NM_001004334.4) | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- IGKV2-24 | c.131G>T p.R44M | Missense Mutation (SNP) | VAF 93/177 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MAGEB1 | c.139del p.D47Ifs*62 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | called by mutect2, pindel, varscan2
- MAGEB4 | c.1013_1014del p.T338Ifs*3 | Frame Shift Del (DEL) | VAF 7/66 reads (11%) | called by pindel, varscan2
- MEGF10 | c.1255del p.A419Qfs*6 | Frame Shift Del (DEL) | VAF 37/84 reads (44%) | called by mutect2, pindel, varscan2
- MYH7 | c.635del p.G212Afs*52 | Frame Shift Del (DEL) | VAF 14/103 reads (14%) | called by mutect2, pindel, varscan2
- PCDH11X | c.3212del p.G1071Efs*50 | Frame Shift Del (DEL) | VAF 78/219 reads (36%) | called by mutect2, pindel, varscan2
- SCIN | c.749_753del p.K250Ifs*29 (on ENST00000297029 / NM_001112706.3; = p.K3Ifs*29 on NM_033128.3) | Frame Shift Del (DEL) | VAF 94/204 reads (46%) | called by mutect2, pindel, varscan2
- SOAT1 | c.1526dup p.L509Ffs*54 | Frame Shift Ins (INS) | VAF 28/193 reads (15%) | called by mutect2, pindel, varscan2
- SOX1 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.939); called by mutect2, varscan2
- SUPT20HL2 | c.1131C>G p.S377R | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM150B | c.13del p.L5Cfs*3 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- WDR75 | c.1868dup p.I624Yfs*18 | Frame Shift Ins (INS) | VAF 44/222 reads (20%) | called by mutect2, pindel, varscan2
- WFDC12 | c.315_328del p.T106Efs*20 | Frame Shift Del (DEL) | VAF 20/75 reads (27%) | called by mutect2, pindel, varscan2
- AASDHPPT | c.36A>G p.P12= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as COSV99593390; called by muse, mutect2, varscan2
- ABCB4 | c.330A>G p.E110= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV99710986; called by muse, mutect2, varscan2
- ABCC2 | c.2373G>C p.V791= | Silent (SNP) | VAF 30/73 reads (41%) | catalogued as COSV100966653; called by muse, mutect2, varscan2
- ACSM2B | c.1500C>A p.V500= | Silent (SNP) | VAF 40/125 reads (32%) | catalogued as COSV100313027; called by muse, mutect2, varscan2
- ADCY8 | c.1030C>A p.R344= | Silent (SNP) | VAF 72/175 reads (41%) | catalogued as COSV53895915, COSV53906214; called by muse, mutect2, varscan2
- ARFGEF2 | c.1812G>T p.G604= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as rs1200368296, COSV100904403; called by muse, mutect2, varscan2
- ARHGAP31 | c.1338A>T p.T446= | Silent (SNP) | VAF 108/199 reads (54%) | catalogued as COSV99957527; called by muse, mutect2, varscan2
- ARHGEF11 | c.2248C>T p.L750= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs368545602; called by muse, mutect2, varscan2
- ATP11C | c.591T>A p.I197= | Silent (SNP) | VAF 72/175 reads (41%) | catalogued as COSV100558387; called by muse, mutect2, varscan2
- ATP7A | c.4215C>T p.L1405= | Silent (SNP) | VAF 41/211 reads (19%) | catalogued as COSV100431418; called by muse, mutect2, varscan2
- B3GAT1 | c.39C>T p.I13= | Silent (SNP) | VAF 42/123 reads (34%) | catalogued as rs185221306, COSV56995382; called by muse, mutect2, varscan2
- BTN2A2 | c.576C>G p.A192= | Silent (SNP) | VAF 38/125 reads (30%) | catalogued as COSV100760547; called by muse, mutect2, varscan2
- CA1 | c.525C>A p.A175= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV99810281; called by muse, mutect2, varscan2
- CABIN1 | c.1191C>A p.V397= | Silent (SNP) | VAF 26/181 reads (14%) | catalogued as COSV99573792; called by muse, mutect2, varscan2
- CACNA1E | c.631T>C p.L211= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as rs1376508293, COSV100704482; called by muse, mutect2, varscan2
- CACNA1F | c.798G>C p.T266= | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as COSV100545243; called by muse, mutect2
- CAPRIN1 | c.528A>G p.P176= | Silent (SNP) | VAF 69/145 reads (48%) | catalogued as rs1482767649, COSV100404147; called by muse, mutect2, varscan2
- CDH6 | c.2082C>G p.P694= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV54078647, COSV99420279; called by muse, mutect2, varscan2
- CHD6 | c.7653G>T p.P2551= | Silent (SNP) | VAF 60/186 reads (32%) | catalogued as COSV100951283; called by muse, mutect2, varscan2
- CLASRP | c.1041A>G p.A347= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV99674051; called by muse, mutect2, varscan2
- CNIH3 | c.324T>C p.C108= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as COSV99686159; called by muse, mutect2, varscan2
- CNOT11 | c.864G>T p.P288= | Silent (SNP) | VAF 62/174 reads (36%) | catalogued as rs770214344, COSV56819420; called by muse, mutect2, varscan2
- COL12A1 | c.6648G>T p.G2216= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV100486330; called by muse, mutect2
- COL17A1 | c.3132A>G p.P1044= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV100793286; called by muse, mutect2, varscan2
- COL5A1 | c.1794C>A p.G598= | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as COSV100880349; called by muse, mutect2, varscan2
- COL6A3 | c.3552T>C p.F1184= | Silent (SNP) | VAF 29/57 reads (51%) | catalogued as COSV99800407; called by muse, mutect2, varscan2
- CRACD | c.1896C>G p.A632= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99949800; called by muse, mutect2
- CREB3L3 | c.33T>G p.A11= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as COSV99314406; called by muse, mutect2, varscan2
- CSMD2 | c.660G>T p.S220= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV99584077; called by muse, mutect2, varscan2
- CYLC1 | c.123C>A p.L41= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV100255128; called by muse, mutect2, varscan2
- DGKQ | c.2685C>A p.V895= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV99298082; called by muse, mutect2, varscan2
- DNAH17 | c.4890C>G p.G1630= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV101103135; called by muse, mutect2, varscan2
- ENPP3 | c.15G>A p.L5= | Silent (SNP) | VAF 41/116 reads (35%) | catalogued as rs754266041, COSV100717830; called by muse, mutect2, varscan2
- EPHA6 | c.3300C>T p.V1100= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as rs762462873, COSV101064893; called by muse, mutect2, varscan2
- EZH1 | c.603G>A p.K201= | Silent (SNP) | VAF 23/123 reads (19%) | catalogued as COSV101331415; called by muse, mutect2, varscan2
- FAAH2 | c.873C>T p.I291= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs1336896438, COSV100887408, COSV66508000; called by muse, mutect2
- FGD1 | c.1482C>T p.I494= | Silent (SNP) | VAF 19/130 reads (15%) | catalogued as COSV100911001, COSV100911224; called by muse, mutect2, varscan2
- FLG2 | c.6639C>T p.S2213= | Silent (SNP) | VAF 214/543 reads (39%) | catalogued as COSV101166085; called by muse, mutect2, varscan2
- FOXP3 | c.807T>G p.A269= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100873224; called by muse, mutect2, varscan2
- GAGE12H | c.114A>T p.P38= | Silent (SNP) | VAF 119/436 reads (27%) | catalogued as COSV101099174; called by muse, mutect2, varscan2
- GAL3ST2 | c.294C>T p.F98= | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as rs369054425; called by muse, mutect2, varscan2
- GPR142 | c.1035G>T p.R345= | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as COSV100170943, COSV59519927; called by muse, varscan2
- GPR142 | c.1122C>A p.V374= | Silent (SNP) | VAF 26/192 reads (14%) | catalogued as COSV100170946; called by muse, varscan2
- GPR149 | c.96G>T p.L32= | Silent (SNP) | VAF 74/111 reads (67%) | catalogued as COSV101078642; called by muse, mutect2, varscan2
- GPR34 | c.39C>T p.V13= | Silent (SNP) | VAF 25/175 reads (14%) | catalogued as COSV100587580, COSV59372224; called by muse, varscan2
- GPRIN1 | c.1176G>T p.T392= | Silent (SNP) | VAF 31/64 reads (48%) | catalogued as COSV99992018; called by muse, mutect2, varscan2
- GRIPAP1 | c.375G>A p.G125= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV100904358; called by muse, mutect2, varscan2
- GSDMC | c.1314C>T p.F438= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV99416268; called by muse, mutect2, varscan2
- HOXA11 | c.102G>T p.L34= | Silent (SNP) | VAF 59/130 reads (45%) | catalogued as rs1483750355, COSV99136080; called by muse, mutect2, varscan2
- HOXB5 | c.573G>A p.G191= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV99494682; called by muse, mutect2
- HOXB7 | c.435C>A p.T145= | Silent (SNP) | VAF 46/120 reads (38%) | catalogued as COSV99494153; called by muse, mutect2, varscan2
- HUWE1 | c.8607G>A p.E2869= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV99473647; called by muse, mutect2, varscan2
- HUWE1 | c.1005C>G p.V335= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV53358373, COSV99473651; called by muse, mutect2, varscan2
- IGHA2 | c.687G>T p.L229= | Silent (SNP) | VAF 25/114 reads (22%) | called by muse, mutect2, varscan2
- IGSF3 | c.1743A>T p.T581= (on ENST00000369486 / NM_001007237.3; = p.T601= on NM_001542.4) | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs765113070, COSV100604996; called by muse, mutect2, varscan2
- IKBKE | c.162G>A p.R54= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as COSV100898356; called by muse, mutect2, varscan2
- IRF2BP1 | c.1539C>T p.T513= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as rs1373873796, COSV100138970; called by muse, mutect2, varscan2
- KLHL34 | c.1275G>A p.E425= | Silent (SNP) | VAF 4/11 reads (36%) | called by mutect2, varscan2
- KMT2D | c.10581G>T p.V3527= | Silent (SNP) | VAF 42/248 reads (17%) | catalogued as COSV99984739; called by muse, mutect2, varscan2
- KRT31 | c.150C>G p.G50= | Silent (SNP) | VAF 43/211 reads (20%) | catalogued as COSV99290018; called by muse, mutect2, varscan2
- KRT34 | c.873G>T p.T291= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as COSV101222702; called by muse, mutect2, varscan2
- KRT40 | c.591G>C p.G197= | Silent (SNP) | VAF 28/133 reads (21%) | catalogued as COSV100898886; called by muse, mutect2, varscan2
- KRT82 | c.1152G>T p.G384= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as rs775738597, COSV99233799; called by muse, mutect2, varscan2
- LHFPL3 | c.300C>A p.L100= | Silent (SNP) | VAF 29/119 reads (24%) | catalogued as COSV101308661; called by muse, mutect2, varscan2
- LMO7 | c.4800C>G p.S1600= (on ENST00000357063; = p.S1281= on NM_005358.5) | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV100413725; called by muse, mutect2, varscan2
- LRFN2 | c.363G>T p.R121= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs879093591, COSV100599808; called by muse, mutect2, varscan2
- LRRC15 | c.1140C>G p.L380= | Silent (SNP) | VAF 41/75 reads (55%) | catalogued as COSV100752860, COSV61649632; called by muse, mutect2, varscan2
- LRRC32 | c.435G>A p.L145= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as rs749681420, COSV99477189; called by muse, mutect2, varscan2
- LRRC7 | c.2817C>A p.P939= (on ENST00000651989 / NM_001370785.2; = p.P906= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 25/96 reads (26%) | catalogued as COSV99228793; called by muse, mutect2, varscan2
- MAGEB6 | c.57T>C p.N19= | Silent (SNP) | VAF 26/100 reads (26%) | catalogued as rs753831889, COSV100983823; called by muse, mutect2, varscan2
- MAN2B1 | c.1290C>T p.S430= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs757526946, COSV99667218; called by muse, mutect2, varscan2
- MARF1 | c.2811C>G p.L937= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as COSV100706188; called by muse, mutect2, varscan2
- MASP1 | c.648C>A p.I216= | Silent (SNP) | VAF 30/220 reads (14%) | catalogued as COSV99397540; called by muse, mutect2, varscan2
- MCHR1 | c.651C>A p.P217= | Silent (SNP) | VAF 49/208 reads (24%) | catalogued as COSV99967881; called by muse, mutect2, varscan2
- MID1 | c.393G>A p.V131= | Silent (SNP) | VAF 25/101 reads (25%) | catalogued as COSV58193690; called by muse, mutect2, varscan2
- MOB3A | c.345G>C p.A115= | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as COSV100830065; called by muse, mutect2, varscan2
- MORF4L2 | c.798T>C p.N266= | Silent (SNP) | VAF 63/174 reads (36%) | catalogued as COSV100846390; called by muse, mutect2, varscan2
- MS4A14 | c.45T>A p.T15= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as COSV100279709; called by muse, mutect2, varscan2
- MYH14 | c.2311C>T p.L771= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as rs776082592, COSV99223653; called by muse, mutect2, varscan2
- MYOM3 | c.2802A>G p.K934= | Silent (SNP) | VAF 24/108 reads (22%) | catalogued as COSV100293503; called by muse, mutect2, varscan2
- NALCN | c.453C>A p.I151= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV99216906; called by muse, mutect2, varscan2
- NCAN | c.1023G>T p.R341= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV99387990; called by muse, mutect2, varscan2
- NECTIN4 | c.108C>A p.T36= | Silent (SNP) | VAF 30/131 reads (23%) | catalogued as rs575343594, COSV100920008; called by muse, mutect2, varscan2
- NEK1 | c.897G>C p.S299= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as COSV101455780, COSV71457165; called by muse, mutect2
- NLGN4X | c.370C>T p.L124= | Silent (SNP) | VAF 30/197 reads (15%) | catalogued as COSV99323330; called by muse, mutect2, varscan2
- NLRC5 | c.5085A>T p.L1695= | Silent (SNP) | VAF 51/99 reads (52%) | catalogued as COSV99347959; called by muse, mutect2, varscan2
- OR10S1 | c.42G>A p.T14= | Silent (SNP) | VAF 77/207 reads (37%) | catalogued as rs748517163, COSV73342691; called by muse, mutect2, varscan2
- OR2G3 | c.783A>G p.Q261= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV60680806; called by muse, mutect2
- OR2M2 | c.486C>A p.A162= | Silent (SNP) | VAF 114/352 reads (32%) | catalogued as rs781780367, COSV100677291; called by muse, mutect2, varscan2
- OR2M3 | c.651C>A p.S217= | Silent (SNP) | VAF 167/476 reads (35%) | catalogued as COSV101513494; called by muse, mutect2, varscan2
- OR2T1 | c.372C>A p.A124= | Silent (SNP) | VAF 37/163 reads (23%) | catalogued as COSV100822343; called by muse, mutect2, varscan2
- OR2T12 | c.915G>T p.T305= | Silent (SNP) | VAF 50/265 reads (19%) | catalogued as COSV58778078, COSV58779366; called by muse, mutect2
- OR4D6 | c.135T>A p.I45= | Silent (SNP) | VAF 28/79 reads (35%) | catalogued as COSV100271790; called by muse, mutect2, varscan2
- OR4K5 | c.852C>T p.P284= | Silent (SNP) | VAF 24/258 reads (9%) | catalogued as rs1473055773, COSV60005317; called by muse, mutect2
- OR51I1 | c.120C>A p.S40= | Silent (SNP) | VAF 38/135 reads (28%) | catalogued as COSV100971776; called by muse, mutect2, varscan2
- OR5D16 | c.378G>A p.V126= | Silent (SNP) | VAF 26/100 reads (26%) | catalogued as COSV101004096, COSV65722535; called by muse, mutect2, varscan2
- OR6C74 | c.66G>A p.Q22= | Silent (SNP) | VAF 55/155 reads (35%) | catalogued as COSV100667820; called by muse, mutect2, varscan2
- OR6N1 | c.483C>G p.S161= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV58650840; called by muse, mutect2, varscan2
- OXR1 | c.2058C>T p.D686= (on ENST00000442977 / NM_001198532.1; = p.D658= on NM_018002.3) | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as rs763454476, COSV99861141; called by muse, mutect2, varscan2
- OXR1 | c.2346A>G p.P782= (on ENST00000442977 / NM_001198532.1; = p.P754= on NM_018002.3) | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as rs1300319308, COSV99861146; called by muse, mutect2, varscan2
- PAPPA2 | c.2931C>G p.S977= | Silent (SNP) | VAF 60/328 reads (18%) | catalogued as COSV100867602, COSV100868442; called by muse, varscan2
- PCDHGB7 | c.2403G>A p.K801= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV99543894; called by muse, mutect2, varscan2
- PHF21B | c.1390T>C p.L464= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV100504038, COSV100504039; called by muse, mutect2
- PKHD1 | c.1260C>A p.G420= | Silent (SNP) | VAF 18/169 reads (11%) | catalogued as COSV100584124; called by muse, mutect2, varscan2
- PLA1A | c.231G>T p.G77= | Silent (SNP) | VAF 36/306 reads (12%) | catalogued as COSV99846001; called by muse, varscan2
- PLA1A | c.246G>T p.L82= | Silent (SNP) | VAF 162/272 reads (60%) | catalogued as COSV99846002; called by muse, varscan2
- PLXNA3 | c.4284G>A p.L1428= | Silent (SNP) | VAF 48/186 reads (26%) | catalogued as COSV100860167; called by muse, mutect2, varscan2
- POU3F3 | c.1089C>T p.F363= | Silent (SNP) | VAF 28/128 reads (22%) | catalogued as COSV63721215; called by muse, mutect2, varscan2
- PRAMEF14 | c.9C>A p.I3= | Silent (SNP) | VAF 54/185 reads (29%) | called by muse, mutect2, varscan2
- PRLR | c.1653G>T p.G551= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV99184649; called by muse, mutect2, varscan2
- PROX1 | c.1320C>A p.P440= | Silent (SNP) | VAF 31/164 reads (19%) | catalogued as COSV99799993; called by muse, mutect2, varscan2
- PRPF8 | c.3123G>A p.V1041= | Silent (SNP) | VAF 62/213 reads (29%) | catalogued as rs761433743, COSV100517774; called by muse, mutect2, varscan2
- PRSS35 | c.672G>T p.R224= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV100864129; called by muse, mutect2, varscan2
- PTCHD1 | c.444C>T p.C148= | Silent (SNP) | VAF 24/130 reads (18%) | catalogued as COSV101037925; called by muse, mutect2, varscan2
- PTPN11 | c.1029G>A p.R343= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV100692474, COSV100692827; called by muse, mutect2, varscan2
- RADX | c.468G>C p.G156= | Silent (SNP) | VAF 60/265 reads (23%) | catalogued as COSV100998895; called by muse, mutect2, varscan2
- RNF40 | c.1047T>A p.R349= | Silent (SNP) | VAF 40/165 reads (24%) | catalogued as COSV100222268; called by muse, mutect2, varscan2
- RTL9 | c.1812A>T p.P604= | Silent (SNP) | VAF 44/104 reads (42%) | catalogued as COSV101511766; called by muse, varscan2
- SCYL2 | c.1413C>T p.I471= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as rs772210503, COSV62568251; called by muse, mutect2, varscan2
- SDK2 | c.2073G>A p.T691= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as rs371984433; called by muse, mutect2, varscan2
- SEMA4D | c.2208C>A p.L736= | Silent (SNP) | VAF 15/23 reads (65%) | catalogued as COSV100358651; called by muse, mutect2, varscan2
- SFTPD | c.672T>A p.V224= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as COSV100954553; called by muse, mutect2, varscan2
- SH3BP5 | c.897G>A p.S299= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs759244501, COSV99508476; called by muse, mutect2, varscan2
- SHKBP1 | c.1419A>G p.P473= | Silent (SNP) | VAF 60/194 reads (31%) | catalogued as COSV99199098; called by muse, mutect2, varscan2
- SLC16A14 | c.618G>A p.G206= | Silent (SNP) | VAF 19/112 reads (17%) | catalogued as rs1481828105, COSV99725788; called by muse, mutect2, varscan2
- SLC1A6 | c.183G>T p.L61= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV55669104, COSV99694065; called by muse, mutect2, varscan2
- SLC2A13 | c.1134A>G p.T378= | Silent (SNP) | VAF 49/160 reads (31%) | catalogued as COSV99786888; called by muse, mutect2, varscan2
- SLC2A2 | c.753T>C p.D251= | Silent (SNP) | VAF 77/143 reads (54%) | catalogued as COSV100049465; called by muse, mutect2, varscan2
- SLC35A2 | c.178T>C p.L60= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV99900411; called by muse, mutect2, varscan2
- SLC38A2 | c.498C>T p.L166= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as COSV99874051; called by muse, mutect2, varscan2
- SLCO6A1 | c.1335C>A p.S445= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV101134789; called by muse, mutect2, varscan2
- SLIT3 | c.3831C>A p.L1277= | Silent (SNP) | VAF 26/145 reads (18%) | catalogued as COSV100269177, COSV60590747; called by muse, mutect2, varscan2
- SPATA20 | c.1671C>A p.T557= (on ENST00000356488 / NM_001258372.1; = p.T573= on NM_022827.4) | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as COSV50066462, COSV99136459; called by muse, mutect2, varscan2
- SPATA6 | c.576G>A p.K192= | Silent (SNP) | VAF 16/95 reads (17%) | catalogued as COSV100893360; called by muse, mutect2, varscan2
- STAB2 | c.2466C>A p.L822= | Silent (SNP) | VAF 32/121 reads (26%) | catalogued as COSV101186199, COSV66334403; called by muse, mutect2, varscan2
- STAT1 | c.1599C>G p.P533= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as COSV100738795; called by muse, mutect2, varscan2
- SUN5 | c.888C>T p.F296= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as rs554316199, COSV62180640; called by muse, mutect2, varscan2
- TAS2R42 | c.138C>T p.F46= | Silent (SNP) | VAF 68/242 reads (28%) | catalogued as rs1268220275, COSV100516906; called by muse, mutect2, varscan2
- TBPL2 | c.25C>A p.R9= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as rs1419487918, COSV55972404, COSV99905498; called by muse, mutect2, varscan2
- TCHH | c.3829C>A p.R1277= | Silent (SNP) | VAF 46/141 reads (33%) | catalogued as rs2496252, COSV100915334; called by muse, mutect2, varscan2
- TEKT3 | c.861G>T p.V287= | Silent (SNP) | VAF 30/74 reads (41%) | catalogued as COSV100107233; called by muse, mutect2, varscan2
- TNR | c.1758C>A p.A586= | Silent (SNP) | VAF 73/235 reads (31%) | catalogued as COSV54901084, COSV99690854; called by muse, mutect2, varscan2
- TPP2 | c.2877A>T p.I959= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV101060375; called by muse, mutect2, varscan2
- TRAPPC3 | c.177C>T p.F59= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV100920340, COSV64264243; called by muse, mutect2, varscan2
- TRIB2 | c.441G>C p.L147= | Silent (SNP) | VAF 54/95 reads (57%) | catalogued as COSV50225273, COSV99331287; called by muse, mutect2, varscan2
- TTN | c.51883C>A p.R17295= (on ENST00000591111; = p.R9871= on NM_003319.4) | Silent (SNP) | VAF 19/106 reads (18%) | catalogued as CM121820, COSV100623914; called by muse, mutect2, varscan2
- TWIST1 | c.534G>T p.V178= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs758354732, COSV99643146; called by muse, mutect2, varscan2
- VIL1 | c.1260C>T p.H420= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV99945788; called by muse, mutect2, varscan2
- WDR11 | c.2148C>T p.I716= | Silent (SNP) | VAF 21/180 reads (12%) | catalogued as rs751148257, COSV54788029; called by muse, mutect2, varscan2
- WDR45 | c.525G>T p.A175= (on ENST00000376372 / NM_001029896.2; = p.A176= on NM_007075.3) | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV100540352; called by mutect2, varscan2
- ZNF114 | c.1155G>A p.E385= | Silent (SNP) | VAF 30/113 reads (27%) | catalogued as COSV100252128; called by muse, mutect2, varscan2
- ZNF595 | c.100T>C p.L34= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV100227844; called by mutect2, varscan2
- AL353804.4 | chrX:73822960 A>G | 5'Flank (SNP) | VAF 34/71 reads (48%) | called by muse, mutect2, varscan2
- CACNA2D1 | c.1931-701del | Intron (DEL) | VAF 11/43 reads (26%) | called by mutect2, pindel, varscan2
- CFAP47 | c.5536-413C>T | Intron (SNP) | VAF 10/53 reads (19%) | catalogued as COSV100545615; called by muse, mutect2, varscan2
- DNM1P46 | n.637G>C | RNA (SNP) | VAF 19/38 reads (50%) | called by muse, mutect2, varscan2
- GAD1 | c.1120-492G>A | Intron (SNP) | VAF 23/70 reads (33%) | catalogued as rs750099269; called by muse, mutect2, varscan2
- IBTK | c.-1G>T | 5'UTR (SNP) | VAF 38/138 reads (28%) | catalogued as COSV100091234; called by muse, mutect2, varscan2
- KLRA1P | n.735A>T | RNA (SNP) | VAF 23/55 reads (42%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85675C>A | Intron (SNP) | VAF 33/145 reads (23%) | catalogued as COSV72275493; called by muse, mutect2, varscan2
- MC3R | c.-63A>T | 5'UTR (SNP) | VAF 111/306 reads (36%) | catalogued as COSV99710779; called by muse, mutect2, varscan2
- NXF5 | n.1495T>C | RNA (SNP) | VAF 101/239 reads (42%) | catalogued as rs150060771, COSV99534562; called by muse, mutect2, varscan2
- PHB2 | c.711+100C>G | Intron (SNP) | VAF 9/66 reads (14%) | catalogued as COSV99781246; called by muse, mutect2, varscan2
- RPS26P15 | n.190C>T | RNA (SNP) | VAF 13/62 reads (21%) | called by muse, mutect2, varscan2
- TFAP2A | chr6:10419426 C>A | 5'Flank (SNP) | VAF 32/156 reads (21%) | catalogued as COSV60237293; called by muse, mutect2, varscan2
- TUBB7P | n.210G>T | RNA (SNP) | VAF 40/143 reads (28%) | called by muse, mutect2, varscan2
- Y_RNA | chr14:50083866 G>A | 5'Flank (SNP) | VAF 13/46 reads (28%) | catalogued as rs778005114; called by muse, mutect2, varscan2
